Surgical pathology report (de-identified scan), TCGA case TCGA-BR-4255, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-4255-01A (Primary Tumor).

STOMACH TISSUE CHECKLIST. Specimen type: Gastrectomy. Tumor Site: Not specified. Tumor configuration: Exophytic (polypoid). Tumor size: 16.0 x 15.0 cm. Histologic type: Signet ring cell carcinoma. Histologic grade: Poorly differentiated. Extent of invasion: Serosa (visceral peritoneum). Lymph nodes: 4 of 12 positive for metastasis. Margins — Proximal margin: Not specified. Distal margin: Not specified. Omental (radial) margin: Not specified. Lymphatic invasion: Not specified. Venous invasion: Not specified. Perineural invasion: Not specified. Additional pathologic findings: Not specified. Comments: None.

Source: NCI Genomic Data Commons file 7fd0119c-39c0-44e0-8d38-92b4afcc9517 (TCGA-BR-4255.E2B424A3-28D0-4CF8-A3A3-B604456362AA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).